Somatic mutation profile of tumor specimen TCGA-DX-A48U-01A (aliquot TCGA-DX-A48U-01A-11D-A307-09) from TCGA case TCGA-DX-A48U, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 57.1 years (20,853 days).
Specimen TCGA-DX-A48U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16e1a261-5f83-4725-b6d8-e8e88da45e7f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A48U-10A (Blood Derived Normal), aliquot TCGA-DX-A48U-10A-01D-A307-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1d04771-25ff-4d14-bd8d-43504b17c8c5

The open-access MAF lists 20 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Frame Shift Del 3, Silent 3, Splice Site 1, Nonsense Mutation 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>T p.R175L | Missense Mutation (SNP) | VAF 43/49 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ERBB4 | c.2544T>A p.N848K | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100727013; called by muse, mutect2, varscan2
- FER | c.856G>C p.E286Q | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV99813782; called by muse, mutect2, varscan2
- GAD2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 20/47 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.599); catalogued as COSV99393907; called by muse, mutect2, varscan2
- GART | c.2209G>A p.A737T | Missense Mutation (SNP) | VAF 79/145 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as rs372288271; called by muse, mutect2, varscan2
- KHK | c.647G>C p.R216T | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV99565383; called by muse, mutect2, varscan2
- MDM2 | c.632T>C p.I211T | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV99254854; called by muse, mutect2, varscan2
- MTHFD1L | c.584C>G p.A195G | Missense Mutation (SNP) | VAF 62/133 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0.182); catalogued as COSV100943307; called by muse, mutect2, varscan2
- OR51G1 | c.509A>G p.Y170C | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1353257103, COSV100429380; called by muse, mutect2, varscan2
- SLC7A14 | c.542-1G>A p.X181_splice | Splice Site (SNP) | VAF 26/51 reads (51%) | catalogued as rs987028471, COSV99200858; called by muse, mutect2, varscan2
- VPS13B | c.11425C>G p.P3809A | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100663292; called by muse, mutect2, varscan2
- ZNF628 | c.1399T>C p.S467P | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV99220247; called by muse, mutect2
- ZSCAN21 | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 58/106 reads (55%) | catalogued as COSV99461243; called by muse, mutect2, varscan2
- DOCK2 | c.2461del p.E821Sfs*9 | Frame Shift Del (DEL) | VAF 44/102 reads (43%) | called by mutect2, pindel, varscan2
- HMBS | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- PABPC4 | c.2_50del p.M1_?17 | Frame Shift Del (DEL) | VAF 40/270 reads (15%) | called by mutect2, pindel
- PTPRS | c.4961del p.T1654Kfs*59 | Frame Shift Del (DEL) | VAF 41/108 reads (38%) | called by mutect2, pindel, varscan2
- NT5DC1 | c.594T>G p.P198= | Silent (SNP) | VAF 57/126 reads (45%) | catalogued as COSV100127174; called by muse, mutect2, varscan2
- RBAK | c.1236A>G p.R412= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV100806743; called by muse, mutect2, varscan2
- TTC3 | c.5661C>G p.V1887= | Silent (SNP) | VAF 42/86 reads (49%) | catalogued as COSV100695964; called by muse, mutect2, varscan2
